Somatic mutation profile of tumor specimen TCGA-IS-A3K6-01A (aliquot TCGA-IS-A3K6-01A-11D-A21Q-09) from TCGA case TCGA-IS-A3K6, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 55.3 years (20,205 days).
Specimen TCGA-IS-A3K6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 289a019b-f45a-48fa-bf45-e5cca22e63c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IS-A3K6-10A (Blood Derived Normal), aliquot TCGA-IS-A3K6-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd9c90ad-cc6e-45a8-b7c6-6321e7bf18ff

The open-access MAF lists 36 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.808T>G p.F270V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV99662171, COSV99664436, COSV99665501; called by muse, mutect2, varscan2
- AL669918.1 | c.2425G>T p.D809Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV101441053, COSV71271412; called by muse, mutect2, varscan2
- ALAS2 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM950022, COSV100238412; called by muse, mutect2, varscan2
- AP5S1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55694293; called by muse, mutect2, varscan2
- ARFGEF1 | c.5010G>A p.M1670I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99142644; called by muse, mutect2, varscan2
- BNC2 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1484821383, COSV101033468; called by muse, mutect2, varscan2
- C2orf42 | c.1427T>A p.V476E | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV100033914; called by muse, mutect2, varscan2
- CCDC122 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as COSV99866001; called by muse, mutect2, varscan2
- CCNT1 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99980782; called by muse, mutect2, varscan2
- CEP152 | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs866582451, COSV57856458; called by muse, mutect2, varscan2
- CHD7 | c.5494G>T p.E1832* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101418272, COSV101418614, COSV71108154; called by muse, mutect2, varscan2
- CNTLN | c.582A>T p.K194N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99264430; called by muse, mutect2, varscan2
- DNAH5 | c.3242T>A p.M1081K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99450554; called by muse, mutect2
- DTWD1 | c.650C>G p.T217S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99233682; called by muse, mutect2, varscan2
- EEF1G | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as rs1418015966, COSV100240422; called by muse, mutect2, varscan2
- FRMPD2 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100563881; called by muse, mutect2, varscan2
- KRTAP5-10 | c.175T>C p.C59R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV100924145; called by muse, mutect2, varscan2
- LHPP | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs892980490, COSV64329529; called by muse, mutect2, varscan2
- LRRN2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141763834; called by muse, mutect2, varscan2
- MAGI2 | c.2888C>A p.A963E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62704975; called by muse, mutect2
- OR51V1 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV58314846; called by muse, mutect2, varscan2
- OR52L1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs377354838; called by muse, mutect2, varscan2
- PML | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99167346; called by muse, mutect2, varscan2
- SPATA17 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV100861175; called by muse, mutect2, varscan2
- TJP2 | c.3230C>T p.S1077L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99601235; called by muse, mutect2, varscan2
- TRDMT1 | c.620A>T p.E207V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100003977; called by muse, mutect2, varscan2
- ZNF391 | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99772664; called by muse, mutect2, varscan2
- H4C6 | c.32del p.L11* | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, pindel, varscan2
- MAP3K19 | c.2355del p.M786* | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- DNAH3 | c.12168C>T p.S4056= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs567061014, COSV54563479; called by muse, mutect2, varscan2
- LTBP4 | c.2952C>T p.S984= (on ENST00000308370 / NM_001042544.1; = p.S947= on NM_003573.2) | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV99193980; called by muse, mutect2, varscan2
- RBMXL2 | c.192C>T p.A64= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1276142982, COSV100182289; called by muse, mutect2, varscan2
- SDR9C7 | c.81C>T p.Y27= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs747363628, COSV53291083; called by muse, mutect2, varscan2
- STAT2 | c.1272G>A p.V424= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs778077035, COSV100028950; called by mutect2, varscan2
- WNK4 | c.1146G>A p.A382= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1479205751, COSV53820505; called by muse, mutect2, varscan2
